Surgical pathology report (de-identified scan), TCGA case TCGA-59-2372, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Roswell Park, specimen TCGA-59-2372-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT
*******Addendum*******

SPECIMEN(S): A. LEFT OVARIAN MASS
B. RIGHT OVARIAN MASS
C. LEFT PELVIC NODES
D. RIGHT PELVIC NODES
E. PARA AORTIC NODES
F. OMENTUM
G. PORTION FREATER CURVATURE STOMACH

CLINICAL HISTORY:

PRE-OPERATIVE DIAGNOSIS:

Ascites and pelvic mass

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSA: Left ovarian mass, FSB: Right ovarian mass: Papillary serous cystadenocarcinoma

By [REDACTED] called [REDACTED]

GROSS DESCRIPTION:

A. LEFT OVARIAN MASS

Received fresh for frozen section and labeled "left ovarian mass" is an enlarged ovary mass measuring 11.0x8.5x4.0cm and weighing 141gm. The surface of the ovary is a papillary appearance with friable granules on the surface. Dissections reveal tan brown solid stalk attached to a thin fibrous capsule. At one end of the ovary shows multiple loculated cysts containing clear fluid. The wall is approximately 0.1cm in thickness at this area, where the surface of the lining is smooth and gray white. Inside the cyst, focally shows the same kind of tan brown tumor mass. Representative sections are submitted in 9 cassettes.

Cassette 1: frozen section

[page 2 of 4]
[REDACTED]

Cassette 2-8: sections from the papillary tumor mass

Cassette 9: sections from loculated cysts

B. RIGHT OVARIAN MASS

Received fresh for frozen section and labeled "right ovarian mass" is a distorted ovarian mass weighing 109gm, measuring 10x7x3.5cm. There is a thin cyst in one end of the specimen measuring 4cm in greatest dimension with a gray white smooth surface lining in both inner and exterior. However, at the opposite end, the polypoid tumor mass attached on to with fine granular and friable appearance. Sections reveal solid tan yellow appearance. Representative sections are submitted in 9 cassettes,

Cassette 1: frozen section

Cassette 2-9: random sections

C. LEFT PELVIC NODES

Received fresh and labeled "left pelvic lymph nodes" are 2 fragments of fatty tissue aggregating 5.0x1.5x0.5cm. Dissections reveal multiple lymph nodes ranging from 0.5 to 5.0cm in greatest dimension. Lymph nodes are entirely submitted in 3 cassettes.

Cassette 1: multiple lymph nodes

Cassette 2-3: 1 bisected large lymph node

D. RIGHT PELVIC NODES

Received fresh and labeled "right pelvic lymph nodes" are multiple fragments of fatty tissue aggregating 3.0x2.0x0.5cm. Dissections reveal multiple lymph nodes ranging from 0.6 to 1.0cm. Lymph nodes are entirely submitted in 2 cassettes.

E. PARA-AORTIC NODES

Received fresh and labeled "para-aortic nodes" are 2 lymph nodes, each measures 2.0cm. One of the lymph nodes shows tumor involvement. Lymph nodes are entirely submitted in 2 cassettes.

Cassette 1: 1 lymph node

Cassette 2: 1 bisected lymph node, tumor involved

F. OMENTUM

Received fresh and labeled "omentum" is a fragment of omentum measuring 27x5x1cm. Serial sections reveal multiple areas involved by the gray white solid tumor mass ranging from 1.1cm to 5.0cm. Representative sections are submitted in 2 cassettes.

G. PORTION GREATER CURVATURE STOMACH

Received fresh and labeled "portion greater curvature stomach" is a ring shaped mucosa tissue measuring 1cm in length, 3cm in outer ring diameter and 1cm in inner ring diameter. Entirely submitted in 2 cassettes.

[REDACTED]

DIAGNOSIS:

A. OVARY, LEFT MASS, OOPHORECTOMY:

-SEROUS PAPILLARY CYSTADENOCARCINOMA WITH PSAMMOMA BODIES, MEASURING 11 X 8 CM, ARISING FROM BORDERLINE SEROUS PAPILLARY CYSTADENOMA

B. OVARY, RIGHT MASS, OOPHORECTOMY:

-SEROUS PAPILLARY CYSTADENOCARCINOMA MEASURING 10 X 7 CM.

C. LYMPH NODE, LEFT PELVIC, EXCISION:

[REDACTED]

[page 3 of 4]
-
- ONE LYMPH NODE WITH METASTASIS AND CAPSULAR EFFRACTION (1/1).
- D. LYMPH NODE, RIGHT PELVIC, EXCISION:
-LYMPH NODES WITH METASTASIS (2/6).
- E. LYMPH NODE, PARA-AORTIC, EXCISION:
-LYMPH NODES WITH METASTASIS (3/5).
- F. OMENTUM:
-ADIPOSE TISSUE WITH METASTATIC SEROUS PAPILLARY
CYSTADENOCARCINOMA OF THE OVARY.
- G. PORTION GREATER CURVATURE STOMACH, EXCISION:
-GASTRIC MUCOSA WITH NO DIAGNOSTIC ABNORMALITIES.
-NO METASTASIS.

A&B: See template

OVARIAN NEOPLASM TEMPLATE

Specimen type: oophorectomy, right and left
Tumor site and size: right 11cm, left 10cm
Specimen integrity: intact
Gross Surface Involvement: yes
Cut Surface: unilocular cystic with multilocular
Gross Necrosis: no
Histologic Type: epithelial, serous
Histologic Grade: well differentiated
Summary of organs/tissues microscopically involved by tumor: both ovaries and omentum
Venous/Lymphatic Invasion: absent
Implants (only applies to borderline tumors):
Lymph Node Dissection: Right pelvic 2/6
Left pelvic 1/4
Para-aortic 3/5
Additional Pathologic Findings:
Peritoneal Cytology if Tumor Limited to Ovary: pending
NY ESO-1:Negative
Pathologic Stage: pT2 N1 Mx

[page 4 of 4]
ADDENDUM:

This report is issued to correct the typographical error as it appeared in the template. Left pelvic lymph should read 1/1 instead of 1/4.

Thank you to take notice.

Source: NCI Genomic Data Commons file d2445fcb-4600-4894-a47b-09ed5aa415dd (TCGA-59-2372.4411C3E9-2751-45EB-BC8F-E64CA2940A09.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).